Somatic mutation profile of tumor specimen TCGA-AG-4022-01A (aliquot TCGA-AG-4022-01A-01D-1733-10) from TCGA case TCGA-AG-4022, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 59.7 years (21,823 days).
Specimen TCGA-AG-4022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2195faaa-9a2d-40e0-a1df-6ccd297f460d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-4022-10A (Blood Derived Normal), aliquot TCGA-AG-4022-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a817d8ba-20dd-411f-b47c-58fd110ab38c

The open-access MAF lists 102 somatic variants for this specimen: 71 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 27, Nonsense Mutation 4, Frame Shift Del 4, Intron 2, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ASPM | c.2938C>T p.R980* | Nonsense Mutation (SNP) | VAF 63/113 reads (56%) | catalogued as rs199422151, CM092391, COSV54133463, COSV54134529; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 135/214 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 73/122 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs373792254; called by muse, mutect2, varscan2
- AHCYL1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV63209059; called by muse, mutect2, varscan2
- ARC | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV63078909; called by muse, mutect2
- ARHGAP5 | c.3867G>C p.G1289= (on ENST00000345122 / NM_001030055.2; = p.G1288= on NM_001173.3) | Splice Region (SNP) | VAF 17/132 reads (13%) | catalogued as COSV61537516; called by muse, mutect2, varscan2
- C2orf80 | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs756574519, COSV58017729; called by muse, mutect2, varscan2
- CCKBR | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.146); catalogued as rs1372506488, COSV58102293; called by muse, mutect2, varscan2
- CCN5 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763203992, COSV51936580; called by muse, mutect2, varscan2
- CCT4 | c.1512G>T p.L504F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV66701702; called by muse, mutect2, varscan2
- CFHR2 | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100804378; called by muse, mutect2, varscan2
- CLCN6 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 169/286 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs150232531; called by muse, mutect2, varscan2
- CLEC14A | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV60563375; called by muse, mutect2, varscan2
- COL7A1 | c.1835C>T p.T612M | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs752967088, COSV60398331; called by muse, mutect2
- DLG3 | c.1153C>T p.R385C (on ENST00000374360 / NM_021120.4; = p.R48C on NM_020730.3) | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52084719; called by muse, mutect2, varscan2
- DNAH10 | c.8153G>A p.R2718Q (on ENST00000409039; = p.R2657Q on NM_207437.3) | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs764996454, COSV68992929; called by muse, mutect2, varscan2
- DNAH10 | c.12770G>A p.R4257H (on ENST00000409039; = p.R4196H on NM_207437.3) | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs575334271, COSV53020668; called by muse, mutect2
- DNAH2 | c.7276G>A p.A2426T | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs375485186; called by muse, mutect2, varscan2
- DSEL | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.354); catalogued as COSV59492934; called by muse, mutect2, varscan2
- DST | c.21256A>G p.M7086V (on ENST00000361203 / NM_001374722.1; = p.M4783V on NM_015548.5) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55026091; called by muse, mutect2, varscan2
- EDIL3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56908131; called by muse, mutect2, varscan2
- EGR3 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57833018; called by muse, mutect2
- FAT3 | c.12595G>A p.A4199T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.425); catalogued as rs201053443; called by muse, mutect2, varscan2
- FLI1 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs375560426; called by muse, mutect2, varscan2
- GABRB3 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs773257229, COSV54671048, COSV54673017; called by muse, mutect2, varscan2
- HDAC9 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs376682964; called by muse, mutect2
- KIAA2026 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs976179771, COSV67356363; called by muse, mutect2
- KMT2B | c.572A>T p.Q191L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as COSV52891472; called by muse, mutect2, varscan2
- KRT83 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1194656235, COSV53340254; called by muse, varscan2
- LIPC | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761575901, COSV54423064; called by muse, mutect2, varscan2
- MOG | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV65306527; called by muse, mutect2, varscan2
- MPHOSPH8 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV100825203; called by muse, mutect2
- MTMR11 | c.1639A>G p.R547G (on ENST00000439741 / NM_001145862.2; = p.R475G on NM_181873.3) | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs1271417603, COSV54965647; called by muse, mutect2, varscan2
- MYO18A | c.5559G>T p.E1853D | Missense Mutation (SNP) | VAF 113/189 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100572722, COSV62869964; called by muse, mutect2, varscan2
- NLRP4 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs140761924; called by muse, mutect2, varscan2
- NOTCH1 | c.6967T>C p.Y2323H | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.445); catalogued as COSV53030301, COSV99490696; called by muse, mutect2, varscan2
- NPAT | c.2630C>T p.A877V | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.766); catalogued as rs1337627277, COSV53719414; called by muse, mutect2, varscan2
- NRROS | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV60746748; called by muse, mutect2, varscan2
- OR8K3 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs564760965, COSV57131294, COSV57132205; called by muse, mutect2, varscan2
- PCDH17 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs200448406, COSV64976318; called by muse, mutect2, varscan2
- PCDHB8 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.344); catalogued as COSV50790749; called by muse, mutect2, varscan2
- PCED1B | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.657); catalogued as rs750197613, COSV71395452; called by muse, mutect2, varscan2
- PEG10 | c.518G>A p.R173H (on ENST00000482108 / NM_001040152.2; = p.R207H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV71788445; called by muse, mutect2, varscan2
- PIGQ | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as rs760318704, COSV50316794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNLDC1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746765267, COSV51704142; called by muse, mutect2, varscan2
- PTPRM | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100159490; called by muse, mutect2, varscan2
- SIPA1L3 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs754711986, COSV55918780; called by muse, mutect2, varscan2
- SLMAP | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV55850214; called by muse, mutect2, varscan2
- SMARCA1 | c.705C>A p.H235Q | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64412789, COSV64413451; called by muse, mutect2, varscan2
- SPTBN5 | c.5264del p.G1755Efs*44 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as COSV58020808, COSV58023622; called by mutect2, pindel, varscan2
- ST6GALNAC3 | c.162C>G p.Y54* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV60340333; called by muse, mutect2, varscan2
- STAB1 | c.5779C>T p.R1927C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs761753155, COSV58739868; called by muse, mutect2, varscan2
- STAB2 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66341395, COSV66342469; called by muse, mutect2, varscan2
- TMEM151A | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59174299; called by muse, mutect2, varscan2
- TOR2A | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376074923; called by muse, mutect2, varscan2
- TRIP12 | c.498del p.G167Vfs*43 | Frame Shift Del (DEL) | VAF 28/156 reads (18%) | catalogued as COSV52268035; called by mutect2, pindel
- TTN | c.51914T>C p.V17305A (on ENST00000591111; = p.V9881A on NM_003319.4) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | PolyPhen possibly damaging (0.775); catalogued as COSV60183903; called by muse, mutect2, varscan2
- TUBB2B | c.496A>T p.T166S | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); catalogued as rs779519065, COSV99455583; called by muse, mutect2, varscan2
- UQCRC1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99179008; called by muse, mutect2, varscan2
- WT1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as rs1452803548, COSV60076165, COSV60078450; called by muse, mutect2, varscan2
- ZHX1 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as rs1375246942, COSV52876832, COSV52877718; called by muse, mutect2, varscan2
- ZNF100 | c.1333A>T p.T445S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV59748796; called by muse, varscan2
- ZNF800 | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs752851454, COSV56177998; called by muse, mutect2, varscan2
- ZNF823 | c.1043G>A p.R348Q (on ENST00000341191 / NM_001297610.2; = p.R304Q on NM_017507.2) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.042); catalogued as rs1408809958, COSV57872586; called by muse, mutect2, varscan2
- ZNF98 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100757579; called by mutect2, varscan2
- APC | c.1766del p.L589* | Frame Shift Del (DEL) | VAF 41/159 reads (26%) | called by mutect2, pindel, varscan2
- BCL9L | c.39del p.R14Gfs*31 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- MDN1 | c.7926dup p.R2643Tfs*5 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- PCDHGA10 | c.864_869dup p.P289_D290insEP | In Frame Ins (INS) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- ABHD10 | c.57C>A p.G19= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV56325672; called by muse, mutect2, varscan2
- ANXA13 | c.190C>T p.L64= | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as COSV51624834; called by muse, mutect2, varscan2
- BPIFB6 | c.984C>A p.G328= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as COSV100848549; called by muse, mutect2, varscan2
- C2CD5 | c.1914A>G p.E638= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- CORO2B | c.954G>A p.P318= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs746146671, COSV55954970; called by muse, mutect2, varscan2
- CYP1A1 | c.654C>A p.V218= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as COSV65697706; called by muse, mutect2, varscan2
- DOCK1 | c.2028T>C p.F676= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV54748142; called by muse, mutect2, varscan2
- FECH | c.948C>T p.D316= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs375689425; called by muse, mutect2, varscan2
- GDAP1L1 | c.174G>A p.S58= | Silent (SNP) | VAF 76/180 reads (42%) | catalogued as COSV61158018; called by muse, mutect2, varscan2
- KMT2B | c.7920C>T p.D2640= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as rs770718510, COSV53075732; called by muse, mutect2, varscan2
- KRTAP12-2 | c.201C>G p.P67= | Silent (SNP) | VAF 70/334 reads (21%) | catalogued as COSV100555008; called by muse, mutect2, varscan2
- LRP12 | c.900C>T p.R300= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV52631212; called by muse, mutect2, varscan2
- MATN3 | c.1200T>G p.G400= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV68100212; called by muse, mutect2, varscan2
- MYH7 | c.3588C>T p.H1196= | Silent (SNP) | VAF 84/300 reads (28%) | catalogued as rs777394877, COSV100806471; called by muse, mutect2, varscan2
- NR0B1 | c.288G>A p.A96= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as COSV66764071; called by muse, mutect2, varscan2
- OBSL1 | c.5448C>T p.R1816= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs773565629, COSV54707928; called by muse, mutect2
- OR8A1 | c.30A>G p.T10= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV52509239; called by muse, mutect2, varscan2
- PTPN14 | c.955A>C p.R319= | Silent (SNP) | VAF 67/85 reads (79%) | catalogued as COSV100872869; called by muse, mutect2, varscan2
- PYROXD2 | c.1167G>A p.A389= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs538136210, COSV65330652; called by muse, mutect2
- RMND5B | c.882G>A p.A294= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs768206260, COSV51071115; called by muse, mutect2, varscan2
- SIM1 | c.705C>T p.R235= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV53491026; called by muse, mutect2
- SKIL | c.1563C>T p.V521= | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as COSV52059107, COSV52061053; called by muse, mutect2, varscan2
- SLITRK1 | c.420T>C p.N140= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as COSV65676704; called by muse, mutect2, varscan2
- THBS2 | c.768C>T p.G256= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV64680399, COSV64681474; called by muse, mutect2
- UTRN | c.6780A>G p.E2260= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100840293; called by muse, mutect2, varscan2
- ZIC1 | c.834C>T p.R278= | Silent (SNP) | VAF 44/166 reads (27%) | catalogued as COSV51555280; called by muse, mutect2, varscan2
- ZNF280C | c.1590C>T p.C530= | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as rs1026606204, COSV63969394; called by muse, mutect2, varscan2
- CHD4 | c.4642+114C>T | Intron (SNP) | VAF 31/148 reads (21%) | catalogued as COSV100538849; called by muse, mutect2, varscan2
- DLG2 | c.205-65818C>T | Intron (SNP) | VAF 50/164 reads (30%) | catalogued as rs779948886, COSV54663888, COSV99718044; called by muse, mutect2, varscan2
- OSGIN1 | n.750C>T | RNA (SNP) | VAF 68/127 reads (54%) | catalogued as rs1418475206, COSV59676255; called by muse, mutect2, varscan2
- SUPT20HL2 | c.-2C>A | 5'UTR (SNP) | VAF 51/499 reads (10%) | called by muse, mutect2, varscan2
